TCGA case TCGA-B0-4822 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a46f36c3-e886-4efe-945a-0cb2e5b765ef

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Dead; Days to death: 1,111 days (3.0 years).

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 78.8 years (28,774 days); Year of diagnosis: 2002; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Days to follow up: 1,111 days (3.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Normal.
- Calcium: Normal.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-4822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.5; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-B0-4822-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-B0-4822-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-B0-4822-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-4822-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 0.7; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form: Tumor status: With tumor; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,111 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,111 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,111 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-B0-4822-01): tumor purity 0.3, ploidy 2.72, whole-genome doublings 1 (call status: legacy_call).
